Surgical pathology report (de-identified scan), TCGA case TCGA-CN-4731, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-4731-01A (Primary Tumor).

[page 1 of 10]
PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Not stated.
PROCEDURE: Bilateral neck dissection, composite resection.
SPECIFIC CLINICAL QUESTION: Not stated.
OUTSIDE TISSUE DIAGNOSIS: Yes, squamous cell carcinoma.
PRIOR MALIGNANCY: Not stated.
CHEMORADIATION: Not stated.
ORGAN TRANSPLANT: Not stated.
IMMUNOSUPPRESSION: Not stated.
OTHER DISEASES: Not stated.

ADDENDA:

Addendum

Immunohistochemical stains and molecular studies were performed and the results are as follows:

STAIN	RESULT
P16	Negative.
EGFR	3+.
HPV in situ hybridization	Negative.

My signature is attestation that I have personally reviewed the submitted material(s) and the above diagnosis reflects that evaluation.

FINAL DIAGNOSIS:

PART 1: GINGIVA, MIDLINE MAXILLA, BIOPSY –
A. KERATOSIS.
B. NO DYSPLASIA OR TUMOR PRESENT.

PART 2: LIP, LOWER, BIOPSY –

[page 2 of 10]
Pathology Report

INVASIVE SQUAMOUS CELL CARCINOMA.

PART 3: MUCOSA, LEFT ORAL COMMISSURE, BIOPSY –
NO TUMOR PRESENT.

PART 4: NERVE, LEFT INFERIOR ALVEOLAR, BIOPSY –
NO TUMOR PRESENT.

PART 5: NERVE, LEFT LINGUAL, BIOPSY –
NO TUMOR PRESENT.

PART 6: MUCOSA, LEFT RETROMOLAR TRIGONE, BIOPSY –
NO TUMOR PRESENT.

PART 7: MANDIBLE, LOWER LIP AND SKIN, COMPOSITE RESECTION –

- A. INVASIVE SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED (8.5 CM), WITH EXTENSIVE BONE INVASION AND FACIAL SKIN INVOLVEMENT.
- B. PERINEURAL INVASION PRESENT (INCLUDING LARGE NERVE AND INTRANEURAL INVASION).
- C. ANGIOLYMPHATIC INVASION PRESENT.
- D. LEFT MANDIBLE BONE AND ADJACENT DEEP SOFT TISSUE MARGINS INVOLVED BY SQUAMOUS CELL CARCINOMA.
- E. FLOOR OF MOUTH MUCOSAL MARGIN INVOLVED BY SEVERE DYSPLASIA (SEE COMMENT).
- F. LEFT LEVEL 1 LYMPH NODES – METASTATIC SQUAMOUS CELL CARCINOMA IN TWO OF FOUR LYMPH NODES (0.8 CM), (2/4); MICROSCOPIC EXTRACAPSULAR SPREAD PRESENT.
- G. LEFT SUBMANDIBULAR GLAND – NO SIGNIFICANT ABNORMALITIES.
- H. PATHOLOGIC STAGE: pT4a N2c.

PART 8: LYMPH NODES, LEFT NECK LEVELS 2-4, SELECTIVE DISSECTION –
SIXTEEN LYMPH NODES, NO TUMOR PRESENT (0/16).

PART 9: LYMPH NODES, RIGHT NECK, LEVEL 4, SELECTIVE DISSECTION –
SEVEN LYMPH NODES, NO TUMOR PRESENT (0/7).

PART 10: LYMPH NODES, RIGHT NECK, LEVEL 2B, SELECTIVE DISSECTION –
FIVE LYMPH NODES, NO TUMOR PRESENT (0/5).

PART 11: LYMPH NODES, RIGHT NECK, LEVELS 1-4, SELECTIVE DISSECTION –

- A. LEVEL 1 – METASTATIC SQUAMOUS CELL CARCINOMA IN ONE OF THREE LYMPH NODES (0.3 CM) (1/3); NO EXTRACAPSULAR SPREAD.
- B. LEVEL 2 – THREE LYMPH NODES, NO TUMOR PRESENT (0/3).
- C. LEVEL 3 – EIGHT LYMPH NODES, NO TUMOR PRESENT (0/8).
- D. LEVEL 4 – SIX LYMPH NODES, NO TUMOR PRESENT (0/6).
- E. SUBMANDIBULAR GLAND – NO SIGNIFICANT ABNORMALITIES.

COMMENT:

We have reviewed the original 7AFS frozen section slides which still shows no carcinoma, but only moderate dysplasia with acute mucositis. This was reviewed with Dr. [REDACTED] who concurs.

This case has also been discussed with Dr. [REDACTED]

[page 3 of 10]
Pathology Report

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in a total of 11 parts.

Part 1 received fresh with the patient's name, initials [REDACTED] labeled "midline maxillary gingival biopsy" consists of two irregular portions of pink, soft tissue, each 0.5 x 0.4 x 0.3 cm and entirely submitted following intraoperative consult labeled 1AFS.

Part 2 received fresh with the patient's name, initials [REDACTED] labeled "lower lip" consists of a 1.0 x 0.7 x 0.4 cm resection of cauterized, pink mucosa, entirely submitted labeled 2AFS.

Part 3 received fresh with the patient's name, initials [REDACTED] labeled "left oral commissure" consists of 3 irregular portions of pink mucosa and tan muscle, 1.0 x 1.0 x 0.5 cm in aggregate and entirely submitted following intraoperative consult labeled 3AFS.

Part 4 received fresh with the patient's name, initials [REDACTED] labeled "left inferior alveolar nerve, clip is proximal" consists of 1.2 x 0.2 x 0.2 cm segment of white soft tissue with an attached clip designating proximal aspect.

Ink code: Blue-proximal

The tissue is entirely submitted following intraoperative consult labeled 4AFS.

Part 5 received fresh with the patient's name, initials [REDACTED] labeled "left lingual nerve-clip is proximal" consists of 1.4 x 0.2 x 0.1 cm segment of white soft tissue with an attached clip designating proximal aspect.

Ink code: Blue-proximal

The specimen is entirely submitted following intraoperative consult labeled 5AFS.

Part 6 received fresh with the patient's name, initials [REDACTED] labeled "left retromolar trigone" consists of a 2.5 x 0.6 x 0.3 cm resection of pink-yellow, mucosa, fat and muscle, entirely submitted following intraoperative consult labeled 6AFS.

Part 7 received fresh for frozen section labeled with the patient's name, initials [REDACTED], and "composite resection" consists of a composite resection of tumor with right and left mandible measuring 11.5 x 11.0 x 5.5 cm with an attached 8.0 x 5.0 cm oval excision of skin from the anterior chin, a 4.2 x 3.2 x 1.8 cm left submandibular gland, and a 5.0 x 2.0 cm portion of lower lip.

There is a 4.0 x 1.5 cm ulcerated area on the skin surface which is 0.2 cm inferior to the vermilion border of the lip which ulcerates through to an 8.5 x 6.0 x 5.0 cm firm tumor which ulcerates the floor of mouth in a U-shaped area above the mandible measuring 11.5 cm with a width of 2.4 cm. The ulcerating area in the skin is 1.5 cm from the right skin margin, 1.5 cm from the left skin margin, and 4.5 cm from the inferior skin margin. The bone margins of resection are grossly free of tumor. The left bone margin is 3.0 cm proximal to the angle of the mandible and the right bone margin is 1.5 cm proximal to the angle of the mandible. The tumor involves and replaces the mandibular bone from midline to 2 cm from the left mandible bone margin. The tumor invades and replaces the left mandible and involves the superficial soft tissue up to less than 1 mm from the proximal edge of the left lateral soft tissue.

A lymph node search of the specimen revealed seven potential left level 1 lymph nodes measuring 1.2 to 0.3 cm. The submandibular gland is serially sectioned to reveal tan, unremarkable parenchyma.

The floor of mouth mucosal margin is submitted for frozen section (7AFS).

[page 4 of 10]
Pathology Report

A portion of the tumor is submitted for tissue banking as well as a portion of normal mucosa.

X-rays are taken. Digital images have been taken.

Representative sections are submitted as follows:

7AFS - floor of mouth mucosal margin, en face
7B DR - right bone margin, en face
7C DR - left bone margin, en face
7D DR - tumor with bone at midline
7E - tumor replacing left mandible bone
7F-7G - tumor with skin and lip
7H-7I - tumor lateral to left mandible
7J - tumor at floor of mouth
7K - tumor with left soft tissue edge (inked blue)
7L - right lip/skin margin, en face
7M - left lip/skin edge, en face
7N - inferior skin/soft tissue margin, en face
7O - right mandible gingiva/soft tissue margin, en face
7P - left mandible gingiva/soft tissue margin, en face
7Q - left submandibular gland
7R - four potential lymph nodes (1.2-0.5 cm)
7S - three potential lymph nodes (1.0-0.3 cm).

Part 8 received unfixed with the patient's name, initials [REDACTED] labeled "left neck-levels 2, 3 and 4" consists of a 12.0 x 3.0 x 0.7 cm section of pink-yellow and hemorrhagic fat and soft tissue with an attached black silk suture at the proximal aspect. The specimen is divided into anatomic zones 2, 3 and 4.

Section Code:

8A - B potential lymph nodes, level 2
8C - D potential lymph nodes, level 3
8E - F potential lymph nodes, level 4

Part 9 received unfixed patient's name, initials [REDACTED], labeled "right neck level 4" consists of two irregular excisions of pink-yellow fat and soft tissue, 4.0 x 1.0 x 0.4 cm and 5.0 x 2.5 x 0.5 cm. Potential lymph nodes dissected from the specimen are submitted labeled 9A and 9B.

Part 10 received unfixed with the patient's name, initials [REDACTED] labeled "right neck level 2B" consists of a 3.5 x 1.5 x 0.4 cm resection of cauterized come pink-yellow fat and soft tissue. Potential lymph nodes and fat are submitted labeled 10A and 10B.

Part 11 received unfixed with the patient's name, initials [REDACTED] labeled "right neck level 2, 3 and 4" consists of an unoriented 13.0 x 4.0 x 1.2 cm selective neck dissection.

The submandibular gland is 4.0 x 3.5 x 1.5 cm and grossly unremarkable. The remainder of the tissue consists of pink-yellow fat and lymph nodes.

The specimen is divided into anatomic zones 1, 2, 3 and 4.

Section Code:

11A submandibular gland

[page 5 of 10]
Pathology Report

11B potential lymph nodes, level 1
11C – D potential lymph nodes, level 2
11E – F potential lymph nodes, level 3
11G – H potential lymph nodes, level 4

INTRAOPERATIVE CONSULTATION:

1FS: MAXILLARY GINGIVA, MID LINE, BIOPSY (frozen section)-

- A. BENIGN.
- B. NO TUMOR SEEN.

2FS: LIP, LOWER, BIOPSY (frozen section) –

- A. MALIGNANT.
- B. SQUAMOUS CELL CARCINOMA

3FS: LEFT ORAL COMMISSURE, BIOPSY (frozen section) –

- A. BENIGN.
- B. NO TUMOR SEEN

4FS: LEFT INFERIOR ALVEOLAR NERVE, BIOPSY (frozen section) –

- A. BENIGN.
- B. NO TUMOR SEEN

5FS: LEFT LINGUAL NERVE, BIOPSY (frozen section) –

- A. BENIGN.
- B. NERVE, NO TUMOR SEEN

6FS: RETROMOLAR TRIGONE, LEFT, BIOPSY (frozen section) –

- A. BENIGN.
- B. NO TUMOR SEEN

7FS: COMPOSITE RESECTION, FLOOR OF MOUTH MUCOSA (frozen section) –

- A. BENIGN.
- B. NO TUMOR SEEN

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.
caa

The following statement applies to all immunohistochemistry, insitu hybridization (ISH & FISH), molecular anatomic pathology, and immunofluorescence testing:

The testing was developed and its performance characteristics determined by the [REDACTED], Department of Pathology, as required by the CLIA [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of [REDACTED] to a maximum of [REDACTED].

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

[page 6 of 10]
Pathology Report

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND TUMORS

SPECIMEN TYPE: Resection: Composite resection (right and left mandible and skin)

TUMOR SITE: Oral Cavity

TUMOR SIZE: Greatest dimension: 8.5 cm

HISTOLOGIC TYPE: Squamous cell carcinoma, conventional

HISTOLOGIC GRADE: G3

PATHOLOGIC STAGING (pTNM): pT4a

pN2c

Number of regional lymph nodes examined: 52

Number of regional lymph nodes involved: 3

Extra-capsular extension of nodal tumor: Present

pMX

MARGINS: Carcinoma in situ present

Margin(s) involved by tumor

Location(s): left mandible bone and adjacent deep soft tissue margin

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

Present

PERINEURAL INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS: Carcinoma in situ

Epithelial dysplasia

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Midline Maxillary Gingival Biopsy

Taken: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 2: Lip Biopsy

Taken: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 3: Left Oral Commisure

Taken: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 4: Left Inferior Alveolar Nerve

Taken: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 5: Left Lingual Nerve

Taken: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

[page 7 of 10]
Pathology Report

Part 6: Left Retromolar Trigone

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 AFS

Part 7: composite Resection

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 E
H&E x 1 F
DOG1 x 1 G
ANEG x 1 G
H&E Recut x 1 G
IHPV x 1 G
cmet x 1 G
IEGFR x 1 G
IBNKNC x 6 G
H&E x 1 G
IISH x 2 G
P16 x 1 G
V-EGFR x 1 G
H&E x 1 H
H&E x 1 I
H&E x 1 J
H&E x 1 K
H&E x 1 L
H&E x 1 M
H&E x 1 N
H&E x 1 O
H&E x 1 P
H&E x 1 Q
DOG1 x 1 R
ANEG x 1 R
H&E x 1 R
H&E x 1 S
H&E x 1 [REDACTED]
H&E x 1 [REDACTED]
H&E x 1 [REDACTED]
H&E x 1 [REDACTED]

Part 8: Left Neck Levels 2,3, and 4

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 F

Part 9: Right Neck Level 4

Taken: [REDACTED]
Stain/cnt Block

[page 8 of 10]
[REDACTED]

Pathology Report

[REDACTED]

H&E x 1 A
H&E x 1 B

Part 10: Right Neck Level 2B

Taken: [REDACTED]
Stain/cont. Block
H&E x 1 A
H&E x 1 B

Part 11: Right Neck Level 2,3, and 4

Taken: [REDACTED]
Stain/cont. Block
H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 F
H&E x 1 G
H&E x 1 H

ICD-9 Diagnosis Codes: {None Entered}

[REDACTED]

SPECIAL PROCEDURES:

In Situ Procedure

Interpretation

PROBE: LSI *EGFR/CEP7* Dual-Color Probe [REDACTED]
Cytogenetic Location: 7p12 / 7p11.1-q11.1

***EGFR* FISH STUDIES PERFORMED ON THE SQUAMOUS CELL CARCINOMA ARE NEGATIVE.**

Number of cells analyzed: 75
Ratio *EGFR/CEP7*: 1.76
High Polysomy: 0%

SNR (signal to nucleus ratio): 2.7
Low Polysomy: 28(37.3%)
Trisomy: 2(2.7%)
Disomy: 45(60.0%)

PROBE: *c-MET/CEP7*
Cytogenetic Location: 7q31.2 / 7p11.1-q11.1

***C-MET* FISH STUDIES PERFORMED ON THE SQUAMOUS CELL CARCINOMA ARE NEGATIVE FOR AMPLIFICATION.**

Number of cells analyzed: 73
Ratio *c-MET/CEP7*: 1.02

SNR (signal to nucleus ratio): 1.6
High Polysomy: 0%

[page 9 of 10]
Pathology Report

Low Polysomy: 0%
Trisomy: 3(4.1%)
Disomy: 70(96.0%)

My signature is attestation that I have personally reviewed the submitted material(s) and the above diagnosis reflects that evaluation.

Results

EGFR FISH positive:

High Polysomy: $\geq$ four gene copies in $\geq$ 40% of cells

Gene Amplification: Ratio gene/chromosome more than two or $\geq$ 15 gene copies in $\geq$ 10% of cells

EGFR FISH negative:

Disomy: $\leq$ two gene copies in more than 90% of the cells

Trisomy: three gene copies in more than 10% of cells

Low Polysomy: $\geq$ four gene copies in more than 10% but less than 40% of cells

c-MET FISH positive:

Gene Amplification: Ratio gene/chromosome more than two or $\geq$ 15 gene copies in $\geq$ 10% of cells

c-MET FISH negative:

Ratio gene/chromosome less than two or $\leq$ 15 gene copies in $\leq$ 10% of the cells.

References:

[page 10 of 10]
Pathology Report

Source: NCI Genomic Data Commons file 509bea20-dea8-4bd5-a43f-825d3b678f07 (TCGA-CN-4731.84C373FC-95B4-429A-92C1-C96FC474589D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).